Somatic mutation profile of tumor specimen C3L-02957-02 (aliquot CPT0196880006) from CPTAC case C3L-02957, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 56.8 years (20,750 days).
Specimen C3L-02957-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5180b953-e627-4cd1-8643-3f50ca97b7e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02957-31 (Blood Derived Normal), aliquot CPT0197790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c778a75-8a2f-44b0-9ddf-ad6b0190c2f7

The open-access MAF lists 681 somatic variants for this specimen: 465 protein-altering or splice-affecting, 157 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 398, Silent 157, Nonsense Mutation 26, Intron 26, RNA 15, Splice Site 14, Frame Shift Del 9, 3'UTR 8, Splice Region 8, Frame Shift Ins 7, 5'Flank 5, 5'UTR 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 55/440 reads (13%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.12784C>T p.H4262Y | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as rs1030461699; called by muse, mutect2, varscan2
- ACSM1 | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs751725508; called by muse, mutect2
- ACTR8 | c.1451G>A p.G484D | Missense Mutation (SNP) | VAF 19/431 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.231); catalogued as COSV99213495; called by muse, mutect2
- ADAMTS9 | c.2717G>T p.R906M | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99899215; called by muse, mutect2, varscan2
- AGL | c.1877A>T p.H626L | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM128735; called by muse, mutect2
- AHNAK | c.12224G>T p.G4075V | Missense Mutation (SNP) | VAF 49/460 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.06); catalogued as COSV57224849; called by muse, mutect2, varscan2
- AHNAK2 | c.11575G>A p.D3859N | Missense Mutation (SNP) | VAF 34/590 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.727); catalogued as rs1356084881; called by muse, mutect2
- ANKRD30A | c.3148G>T p.E1050* (on ENST00000611781; = p.E994* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV64605238; called by muse, mutect2, varscan2
- ASXL1 | c.3016G>C p.E1006Q | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100039653, COSV60119945; called by muse, mutect2
- ATL3 | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV60297136; called by muse, mutect2, varscan2
- ATP2A3 | c.1811G>T p.R604L | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99988738; called by muse, mutect2, varscan2
- ATXN2 | c.1268C>T p.T423I (on ENST00000550104; = p.T263I on NM_002973.4) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1281319412, COSV66485312; called by muse, mutect2
- B3GAT1 | c.101C>G p.A34G | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.029); catalogued as COSV56995067, COSV99074089; called by muse, mutect2, varscan2
- BBS7 | c.850A>T p.M284L | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52656256; called by muse, mutect2, varscan2
- BMPR1B | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs754365645; ClinVar: uncertain significance; called by muse, mutect2
- BRINP1 | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 69/489 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99777077; called by muse, mutect2, varscan2
- C7orf57 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as COSV100817302; called by muse, mutect2
- CACNA1E | c.1150del p.R384Vfs*4 | Frame Shift Del (DEL) | VAF 46/364 reads (13%) | catalogued as COSV62420197; called by pindel, varscan2
- CBL | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50645966; called by muse, mutect2, varscan2
- CCDC146 | c.1920-1G>A p.X640_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as rs1001616116; called by muse, mutect2, varscan2
- CEP350 | c.912G>C p.Q304H | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV62486030; called by muse, mutect2, varscan2
- CFAP47 | c.4820C>G p.P1607R | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs1191221219; called by muse, mutect2
- CHST2 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58886767; called by muse, mutect2, varscan2
- CIC | c.3641G>T p.R1214L | Missense Mutation (SNP) | VAF 86/383 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.4); catalogued as COSV99358994; called by muse, mutect2, varscan2
- COG8 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 60/496 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs758158339; called by muse, mutect2, varscan2
- COL22A1 | c.4274C>G p.T1425R | Missense Mutation (SNP) | VAF 46/455 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); catalogued as rs1339747295, COSV57368217; called by muse, mutect2
- CPT1C | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 76/324 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54919325; called by muse, mutect2, varscan2
- CPXM1 | c.966C>G p.I322M | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV101013719; called by muse, mutect2
- CREB5 | c.465-1G>T p.X155_splice (on ENST00000357727 / NM_182898.4; = p.X148_splice on NM_004904.3) | Splice Site (SNP) | VAF 27/180 reads (15%) | catalogued as COSV100745680; called by muse, mutect2, varscan2
- CREBBP | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 42/710 reads (6%) | catalogued as COSV52119623, COSV52122303; called by muse, mutect2
- CSDE1 | c.1930G>T p.D644Y (on ENST00000358528 / NM_001007553.3; = p.D613Y on NM_007158.6) | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs138627779; called by muse, mutect2, varscan2
- CSMD3 | c.8845G>T p.E2949* (on ENST00000297405 / NM_001363185.1; = p.E2780* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 16/129 reads (12%) | catalogued as COSV52131625, COSV52243238; called by muse, mutect2, varscan2
- CSMD3 | c.3578G>A p.R1193Q (on ENST00000297405 / NM_001363185.1; = p.R1089Q on NM_052900.3) | Missense Mutation (SNP) | VAF 53/487 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs1323845975, COSV52111209; called by muse, mutect2, varscan2
- DEFB121 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 57/302 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.076); catalogued as rs967966294; called by muse, mutect2, varscan2
- DGKB | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51814491; called by muse, mutect2, varscan2
- DGKI | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 14/135 reads (10%) | catalogued as COSV55967600; called by muse, mutect2, varscan2
- DMD | c.5043G>T p.M1681I | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs1045187121; called by muse, mutect2
- EEF2K | c.1232-1G>C p.X411_splice | Splice Site (SNP) | VAF 12/260 reads (5%) | catalogued as COSV99533736; called by muse, mutect2
- EFHB | c.251T>C p.M84T | Missense Mutation (SNP) | VAF 22/405 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1352640509, COSV99859086; called by muse, mutect2
- EFR3B | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1157170656; called by muse, mutect2, varscan2
- ELAPOR2 | c.2792G>T p.G931V (on ENST00000450689 / NM_001142749.3; = p.G764V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); catalogued as COSV99787969; called by muse, mutect2
- EPHB2 | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 48/518 reads (9%) | catalogued as COSV101006739; called by muse, mutect2
- ERAS | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV99504853; called by muse, mutect2
- EYS | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV65546188; called by muse, mutect2, varscan2
- FAM3A | c.152-8C>A | Splice Region (SNP) | VAF 30/356 reads (8%) | catalogued as rs1451592664; called by muse, mutect2
- FAM71B | c.331C>G p.R111G | Missense Mutation (SNP) | VAF 39/482 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV57228351; called by muse, mutect2
- FER1L5 | c.2398C>T p.H800Y (on ENST00000623019; = p.H805Y on NM_001293083.2) | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV70068998; called by muse, mutect2
- FEZF2 | c.1180T>A p.C394S | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51862538; called by muse, mutect2
- FSTL4 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV99532569; called by muse, mutect2
- FSTL5 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV60228052; called by muse, mutect2, varscan2
- GABRB3 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as rs1453012489, COSV54657264, COSV54676874; called by muse, mutect2
- GPC5 | c.930C>G p.Y310* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as COSV65586625; called by mutect2, varscan2
- GRM5 | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59588946, COSV59634385; called by muse, mutect2
- HAS1 | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 110/461 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768928691; called by muse, mutect2, varscan2
- HCFC1 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV104415485; called by muse, mutect2
- HMX3 | c.413C>A p.A138D | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV63501906; called by muse, mutect2, varscan2
- HOXA3 | c.1291C>G p.Q431E | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100415539, COSV57828754; called by muse, mutect2
- HSPH1 | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as rs1018221389; called by muse, mutect2, varscan2
- HUWE1 | c.10822C>A p.L3608I | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs782349344; called by muse, mutect2
- IFT172 | c.4834C>G p.L1612V | Missense Mutation (SNP) | VAF 23/331 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.158); catalogued as rs894866572, COSV51993893; called by muse, mutect2
- IL21R | c.1124C>A p.S375Y | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100559922; called by muse, mutect2, varscan2
- IPO13 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.079); catalogued as rs981217383; called by muse, mutect2
- ITIH6 | c.1123C>A p.H375N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV54492478; called by muse, mutect2, varscan2
- IVL | c.1666C>A p.Q556K | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.066); catalogued as COSV100908306, COSV64215387; called by muse, mutect2
- JAKMIP2 | c.1501G>C p.G501R | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54602896; called by muse, mutect2, varscan2
- KCNMB4 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.542); catalogued as COSV50691492; called by muse, mutect2, varscan2
- KIRREL1 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100779706; called by muse, mutect2
- LRFN4 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs1355003703; called by muse, mutect2, varscan2
- MAGED2 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54496986; called by muse, mutect2
- MEGF8 | c.3862C>G p.P1288A (on ENST00000251268 / NM_001271938.2; = p.P1221A on NM_001410.3) | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99234863; called by muse, mutect2
- MEIS1 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 11/293 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.146); catalogued as COSV99715630; called by muse, mutect2
- MICAL3 | c.226A>T p.K76* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV52901087; called by muse, mutect2, varscan2
- MMUT | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as CM060366; called by muse, mutect2, varscan2
- MN1 | c.3892G>T p.V1298L | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100180192; called by muse, mutect2
- MROH7 | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.127); catalogued as COSV59877765; called by muse, mutect2
- MUC16 | c.7669A>G p.T2557A | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV104432125; called by muse, mutect2, varscan2
- MYH2 | c.3355-1G>A p.X1119_splice | Splice Site (SNP) | VAF 22/578 reads (4%) | catalogued as rs1346193201; called by muse, mutect2
- MYH9 | c.4324A>C p.K1442Q | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53384414; called by muse, mutect2
- NELL1 | c.1323G>C p.K441N | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.352); catalogued as rs1565066650; called by muse, mutect2
- NEXMIF | c.3719G>T p.G1240V | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.054); catalogued as COSV99029806; called by muse, mutect2
- NHLRC4 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs752615912; called by mutect2, varscan2
- NHS | c.2131G>C p.A711P | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV66275062; called by muse, mutect2
- NUTM1 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV60995244; called by muse, mutect2
- NXPH2 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as rs1289010307; called by muse, mutect2, varscan2
- OGT | c.2335A>G p.M779V | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.003); catalogued as rs1179616611, COSV65481612; called by muse, mutect2
- OR2T8 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 17/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100178462, COSV60664253; called by muse, mutect2
- OR4A16 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.226); catalogued as rs374770148; called by muse, mutect2, varscan2
- OR4C16 | c.347C>A p.T116K | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV58942583; called by muse, mutect2, varscan2
- OR51L1 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205141361; called by muse, mutect2, varscan2
- OR5L1 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs138368201; called by muse, mutect2, varscan2
- PCDHB1 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60630243; called by muse, mutect2
- PCDHB6 | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs572160511; called by muse, mutect2, varscan2
- PDE4B | c.2153C>T p.S718F | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.06); catalogued as COSV58478815; called by muse, mutect2
- PDGFRA | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as COSV57268221; called by muse, mutect2
- PHF6 | c.128A>G p.H43R | Missense Mutation (SNP) | VAF 41/425 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs1273843884; called by muse, mutect2
- PKHD1 | c.8249G>A p.G2750E | Missense Mutation (SNP) | VAF 19/538 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348552972; called by muse, mutect2
- PLXNC1 | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.75); catalogued as COSV99314124; called by muse, mutect2
- PRLR | c.1537C>A p.H513N | Missense Mutation (SNP) | VAF 41/479 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51495662; called by muse, mutect2
- PRND | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 182/636 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs778112087, COSV59896961; called by muse, mutect2, varscan2
- PTPRR | c.1697A>T p.Q566L | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51739696; called by muse, mutect2, varscan2
- PTPRT | c.521C>G p.P174R | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV62019827; called by muse, mutect2, varscan2
- RAG1 | c.1682G>T p.R561L | Missense Mutation (SNP) | VAF 73/424 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as CM981694, COSV55024882; called by muse, mutect2, varscan2
- REG1A | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 111/559 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs777579151, COSV52071733, COSV52072168; called by muse, mutect2, varscan2
- RERE | c.3697G>T p.E1233* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV61940863; called by muse, mutect2, varscan2
- RGS7 | c.722G>A p.S241N | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); catalogued as COSV100471897; called by muse, mutect2, varscan2
- RHOT1 | c.1315C>T p.L439F | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1266417602; called by muse, mutect2
- RIMBP2 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs768170548, COSV55472252; called by mutect2, varscan2
- RNF113A | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65097750; called by muse, mutect2, varscan2
- RP1 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 24/574 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1441547599; called by muse, mutect2
- RRP7A | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1425057669; called by muse, mutect2
- RTL8C | c.110C>A p.T37N | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV99924261; called by muse, mutect2
- SCAF1 | c.970G>C p.A324P | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1289410641, COSV62183197; called by muse, mutect2, varscan2
- SCIN | c.1435C>G p.P479A (on ENST00000297029 / NM_001112706.3; = p.P232A on NM_033128.3) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282876746; called by muse, mutect2
- SGCZ | c.933G>T p.W311C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66039620, COSV66043270; called by muse, mutect2
- SHANK2 | c.3664G>C p.A1222P | Missense Mutation (SNP) | VAF 72/515 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53600959, COSV99573203; called by muse, mutect2, varscan2
- SHISAL1 | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 21/311 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs1453672483; called by muse, mutect2
- SI | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV52300766; called by muse, mutect2, varscan2
- SKI | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 15/549 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs1431331755; called by muse, mutect2
- SLC22A11 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57253215; called by muse, mutect2
- SLC22A25 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs139002638, COSV60598593; called by muse, mutect2, varscan2
- SLCO4A1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1462022689; called by muse, mutect2
- SMG5 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1024380151; called by muse, mutect2
- SORCS1 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 37/346 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53876887; called by muse, mutect2, varscan2
- SRCAP | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52675871; called by muse, mutect2, varscan2
- TIAM1 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); catalogued as COSV54547270; called by muse, mutect2
- TIFAB | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 126/549 reads (23%) | catalogued as COSV72345920; called by muse, mutect2, varscan2
- TMEM265 | c.241G>C p.A81P | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.837); catalogued as COSV52672399; called by muse, mutect2
- TMEM72 | c.336C>A p.H112Q | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101273505; called by muse, mutect2, varscan2
- TREX2 | c.311C>G p.T104R (on ENST00000334497; = p.T61R on NM_080701.3) | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57851036; called by muse, mutect2
- TRIM15 | c.236del p.G79Efs*59 | Frame Shift Del (DEL) | VAF 74/571 reads (13%) | catalogued as COSV64990339; called by mutect2, pindel, varscan2
- TRPM6 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62510944; called by muse, mutect2
- TYROBP | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 28/664 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1364027133; called by muse, mutect2
- USH2A | c.1823G>T p.C608F | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1475577009; called by muse, mutect2
- WDR90 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs1011032155; called by muse, mutect2
- WT1 | c.932G>T p.W311L | Missense Mutation (SNP) | VAF 65/449 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as CM982045, COSV60070783; called by muse, mutect2, varscan2
- XIRP2 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99736892; called by muse, mutect2, varscan2
- XRN2 | c.1773+1G>T p.X591_splice | Splice Site (SNP) | VAF 51/197 reads (26%) | catalogued as rs1324545184; called by muse, mutect2, varscan2
- ZIC3 | c.611G>T p.S204I | Missense Mutation (SNP) | VAF 44/471 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV54976500; called by muse, mutect2
- ZNF189 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs775403415; called by muse, mutect2, varscan2
- ZNF318 | c.2771G>T p.G924V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58930547; called by muse, mutect2, varscan2
- ZNF382 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs773090722, COSV99035401; called by muse, mutect2, varscan2
- ZNF827 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 32/302 reads (11%) | catalogued as COSV65226644; called by muse, mutect2
- ACSF3 | c.478G>T p.V160F | Missense Mutation (SNP) | VAF 42/393 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ADAMTS6 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADARB1 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRG5 | c.1514C>A p.S505Y | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.243); called by muse, mutect2
- AHNAK2 | c.8527G>C p.V2843L | Missense Mutation (SNP) | VAF 38/634 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2
- AIPL1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 48/412 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ALDH1L1 | c.644A>T p.Q215L | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.071); called by muse, mutect2
- AMY2A | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANAPC1 | c.1280C>A p.A427D | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- ANKRD17 | c.5790G>T p.R1930S | Missense Mutation (SNP) | VAF 111/805 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- APBB1IP | c.1687C>T p.L563F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); called by muse, mutect2
- APMAP | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- APOBR | c.2612A>T p.K871M (on ENST00000431282; = p.K880M on NM_018690.4) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2
- APOOL | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 17/377 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- ASH1L | c.3526G>A p.E1176K | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- ATP1A2 | c.2072C>A p.S691Y | Missense Mutation (SNP) | VAF 120/591 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP2B2 | c.1496C>T p.T499I (on ENST00000352432; = p.T465I on NM_001683.5) | Missense Mutation (SNP) | VAF 39/363 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AZGP1 | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.357); called by muse, varscan2
- BBOX1 | c.476C>A p.P159Q | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- BEGAIN | c.1743C>A p.S581R | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BEX4 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- BIVM-ERCC5 | c.2174G>T p.G725V | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BMP4 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- BPTF | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.257); called by muse, mutect2
- BRD3 | c.871A>T p.K291* | Nonsense Mutation (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- BRINP1 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- BRINP2 | c.1799G>T p.S600I | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- C11orf21 | c.375G>C p.R125S (on ENST00000381153 / NM_001329958.2; = p.R171S on NM_001142946.3) | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2
- C16orf96 | c.3250C>A p.P1084T | Missense Mutation (SNP) | VAF 47/417 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- C1QB | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C9 | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CACNG2 | c.874A>T p.R292W | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- CADM2 | c.513T>A p.Y171* (on ENST00000407528 / NM_001167674.2; = p.Y173* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- CADPS2 | c.3562A>G p.I1188V | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.031); called by muse, mutect2
- CAMSAP1 | c.3043G>T p.V1015F | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- CAPN10 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); called by muse, mutect2
- CASK | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- CASQ2 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 28/427 reads (7%) | called by muse, mutect2
- CBLL2 | c.202G>T p.G68W | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC168 | c.111G>T p.W37C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCNC | c.749T>G p.M250R | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CD109 | c.2622G>T p.Q874H | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- CD1E | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CD207 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- CD247 | c.162+1G>T p.X54_splice | Splice Site (SNP) | VAF 32/564 reads (6%) | called by muse, mutect2
- CD300E | c.470C>A p.T157N | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CD4 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDC42BPG | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 32/290 reads (11%) | called by muse, mutect2, varscan2
- CDH2 | c.2716G>C p.D906H | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH9 | c.1250T>C p.I417T | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CELA2B | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 43/331 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CFAP46 | c.1549C>A p.L517M | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CFTR | c.4198T>A p.C1400S | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST8 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 149/550 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CIZ1 | c.1862T>A p.L621Q | Missense Mutation (SNP) | VAF 27/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- CNGA2 | c.1712A>T p.E571V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL11A1 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- COL28A1 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CR2 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 81/499 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- CRYM | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 62/521 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CST4 | c.196C>A p.R66S | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CTPS2 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP11B1 | c.1308G>T p.R436S | Missense Mutation (SNP) | VAF 78/721 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP26B1 | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 40/678 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- CYP4V2 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CYSLTR2 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- DAPK1 | c.3090G>T p.Q1030H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, varscan2
- DCAF8L1 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- DENND1A | c.668G>T p.W223L | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DGKK | c.2724C>A p.Y908* | Nonsense Mutation (SNP) | VAF 23/275 reads (8%) | called by muse, mutect2
- DIAPH2 | c.3305G>T p.*1102Lext*12 | Nonstop Mutation (SNP) | VAF 9/195 reads (5%) | called by muse, mutect2
- DIDO1 | c.6038G>A p.G2013D | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- DISP3 | c.3040G>T p.V1014F | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- DLGAP5 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.802); called by muse, mutect2
- DNAAF6 | c.188C>G p.P63R | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH3 | c.3746A>T p.Q1249L | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- DSE | c.1223C>A p.A408E | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DUSP9 | c.104C>G p.S35W | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- DYNC1H1 | c.5523G>T p.Q1841H | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DYNC2H1 | c.9820-2A>T p.X3274_splice | Splice Site (SNP) | VAF 22/110 reads (20%) | called by mutect2, varscan2
- EDA2R | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- EIF3B | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- EIF4ENIF1 | c.1869A>C p.Q623H | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ELOA2 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 34/866 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2
- EP300 | c.2104A>T p.M702L | Missense Mutation (SNP) | VAF 89/569 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ERBB4 | c.2588G>T p.G863V | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EYS | c.2293G>A p.G765R | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- FAM118A | c.268G>C p.V90L | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); called by muse, mutect2
- FAM166C | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM83C | c.2063A>G p.Q688R | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2
- FAM83C | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- FBXO40 | c.928T>A p.Y310N | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FER1L5 | c.3855G>C p.K1285N (on ENST00000623019; = p.K1258N on NM_001293083.2) | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FFAR3 | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 186/1012 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FLNA | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2
- FLT4 | c.3807+4C>A | Splice Region (SNP) | VAF 38/274 reads (14%) | called by muse, mutect2, varscan2
- FN1 | c.810T>A p.C270* | Nonsense Mutation (SNP) | VAF 83/449 reads (18%) | called by muse, mutect2, varscan2
- FOLH1 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- FOXJ2 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 44/554 reads (8%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2
- FOXL1 | c.46C>G p.P16A | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2
- FRMPD4 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- GALNT8 | c.1042G>T p.V348F | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- GAS6 | c.405C>A p.D135E | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GFRA2 | c.969C>A p.C323* | Nonsense Mutation (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- GLE1 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 14/339 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- GMCL1 | c.1365-2A>T p.X455_splice | Splice Site (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2
- GNB3 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- GPATCH2 | c.1503G>T p.Q501H | Missense Mutation (SNP) | VAF 103/543 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPC6 | c.1067C>A p.A356D | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- GPR139 | c.993C>A p.N331K | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- GPRIN1 | c.1464C>A p.N488K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- GREM2 | c.209G>T p.S70I | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.625); called by muse, mutect2
- GRIK2 | c.2449G>T p.V817F | Missense Mutation (SNP) | VAF 44/378 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- HAPLN3 | c.125-1G>T p.X42_splice | Splice Site (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- HCRTR2 | c.632A>G p.D211G | Missense Mutation (SNP) | VAF 63/511 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HELZ | c.4961C>A p.P1654Q | Missense Mutation (SNP) | VAF 86/404 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- HIC2 | c.1240A>T p.S414C | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.293); called by muse, mutect2
- HK3 | c.322del p.V108* | Frame Shift Del (DEL) | VAF 51/475 reads (11%) | called by pindel, varscan2
- HSF1 | c.564+5G>T | Splice Region (SNP) | VAF 53/355 reads (15%) | called by muse, mutect2, varscan2
- HTATSF1 | c.325A>T p.T109S | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- HYDIN | c.6596G>T p.G2199V | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); called by muse, mutect2
- IDS | c.324C>A p.Y108* | Nonsense Mutation (SNP) | VAF 24/528 reads (5%) | called by muse, mutect2
- IFNL1 | c.301G>T p.V101F | Missense Mutation (SNP) | VAF 147/516 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- IGHM | c.1231T>A p.Y411N | Missense Mutation (SNP) | VAF 50/666 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- IMPDH2 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- INSYN2B | c.1243C>G p.R415G | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- INTS2 | c.3151C>T p.L1051F | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- INTU | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- JAKMIP1 | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2
- JAKMIP2 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KAT8 | c.1006A>G p.S336G | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- KCNA6 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCND3 | c.1603T>A p.S535T | Missense Mutation (SNP) | VAF 49/798 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.223); called by muse, mutect2
- KCNK13 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 19/258 reads (7%) | called by muse, mutect2
- KCNT2 | c.1814G>C p.S605T | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- KIAA0319L | c.574_587del p.P192Yfs*9 | Frame Shift Del (DEL) | VAF 31/351 reads (9%) | called by mutect2, pindel
- KIAA1210 | c.3092dup p.R1032Pfs*10 | Frame Shift Ins (INS) | VAF 31/281 reads (11%) | called by mutect2, pindel, varscan2
- KIAA1614 | c.1195C>A p.Q399K | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.124); called by muse, mutect2
- KIAA1671 | c.4471G>T p.A1491S | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- KIF17 | c.2565G>C p.M855I | Missense Mutation (SNP) | VAF 32/387 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2
- KIF4A | c.1453G>C p.A485P | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.326); called by muse, mutect2
- KIR3DX1 | n.357-1G>A | Splice Site (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- KLHL42 | c.1391T>C p.L464S | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- KLHL42 | c.1392G>T p.L464F | Missense Mutation (SNP) | VAF 42/396 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- KLK9 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.022); called by muse, mutect2
- KREMEN2 | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- L3MBTL2 | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2
- LAMB4 | c.1726C>A p.P576T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2
- LCK | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- LDAH | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- LILRB2 | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- LPAR4 | c.896T>A p.L299H | Missense Mutation (SNP) | VAF 12/369 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- LRP1B | c.7388-1G>T p.X2463_splice | Splice Site (SNP) | VAF 28/115 reads (24%) | called by muse, mutect2, varscan2
- LRRC14B | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2
- LSAMP | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 57/396 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MAGEA1 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- MAGEB6B | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAP2K1 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 16/503 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2
- MFAP3 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MFF | c.761dup p.L254Ffs*11 | Frame Shift Ins (INS) | VAF 57/344 reads (17%) | called by mutect2, pindel, varscan2
- MLYCD | c.1141A>T p.S381C | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MMRN1 | c.1303G>T p.V435F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- MOK | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- MORC1 | c.2187G>T p.L729= | Splice Region (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- MOSPD3 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRGPRX3 | c.172A>G p.R58G | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MRPL57 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 18/664 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.306); called by muse, mutect2
- MTMR8 | c.275A>T p.E92V | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2
- MUC16 | c.41878-1G>T p.X13960_splice | Splice Site (SNP) | VAF 22/169 reads (13%) | called by muse, mutect2, varscan2
- MYOM2 | c.2734G>T p.G912C | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2
- MYOM2 | c.3659A>C p.Y1220S | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MYT1 | c.166dup p.L56Pfs*11 | Frame Shift Ins (INS) | VAF 43/229 reads (19%) | called by mutect2, pindel, varscan2
- MYT1L | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 71/380 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- NAB2 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAV2 | c.1129G>T p.A377S (on ENST00000396087 / NM_001244963.2; = p.A354S on NM_145117.5) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCBP3 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- NDNF | c.1418A>T p.Q473L | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NEURL1 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.991); called by muse, mutect2
- NEUROD4 | c.411G>T p.W137C | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- NF1 | c.60+8G>T | Splice Region (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- NFASC | c.1950dup p.G651Rfs*4 (on ENST00000339876 / NM_001378329.1; = p.G647Rfs*4 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 38/273 reads (14%) | called by mutect2, pindel, varscan2
- NHS | c.3092G>T p.R1031I | Missense Mutation (SNP) | VAF 29/510 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLGN1 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOC2L | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2
- NOX5 | c.80G>T p.W27L | Missense Mutation (SNP) | VAF 46/317 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- NPC2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 18/584 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2
- NSUN5 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- NUP133 | c.2425A>G p.I809V | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NUP205 | c.4784A>T p.D1595V | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NYX | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- OCEL1 | c.673-2A>T p.X225_splice | Splice Site (SNP) | VAF 4/75 reads (5%) | called by muse, mutect2
- OGN | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR10K2 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.448); called by muse, varscan2
- OR10Z1 | c.473del p.G158Efs*2 | Frame Shift Del (DEL) | VAF 45/353 reads (13%) | called by mutect2, pindel, varscan2
- OR11H6 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2
- OR11H6 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2
- OR2A2 | c.760G>C p.A254P | Missense Mutation (SNP) | VAF 9/254 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2
- OR2C3 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- OR2G3 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR3A3 | c.691del p.V231* | Frame Shift Del (DEL) | VAF 52/457 reads (11%) | called by mutect2, pindel, varscan2
- OR5B3 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- OR5H1 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2
- OSBPL2 | c.618C>A p.F206L (on ENST00000313733 / NM_144498.4; = p.F194L on NM_014835.4) | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2
- P2RY10 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PABPC5 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2
- PAPLN | c.3017A>T p.E1006V (on ENST00000554301; = p.E979V on NM_173462.4) | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2
- PAQR7 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 53/290 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PBX1 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2
- PCDH19 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA10 | c.1419C>G p.I473M | Missense Mutation (SNP) | VAF 52/868 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PCDHB1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PEDS1 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 96/437 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PEX5L | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2
- PHKB | c.2008T>G p.F670V | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- PIEZO2 | c.5180C>G p.P1727R | Missense Mutation (SNP) | VAF 15/388 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- PLA2G6 | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 48/596 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.377); called by muse, mutect2
- PLAG1 | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2
- PLSCR4 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); called by muse, mutect2
- PLXNB3 | c.3688G>T p.G1230C | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARG | c.1497G>T p.E499D (on ENST00000287820 / NM_015869.5; = p.E469D on NM_005037.7) | Missense Mutation (SNP) | VAF 22/440 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2
- PPP1R3F | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.481); called by muse, mutect2
- PRDM9 | c.1625A>T p.H542L | Missense Mutation (SNP) | VAF 32/568 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); called by muse, mutect2
- PREX1 | c.3971A>T p.D1324V | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKACG | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 68/395 reads (17%) | called by muse, mutect2, varscan2
- PRKX | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 33/373 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRPF3 | c.1167del p.W389Cfs*6 | Frame Shift Del (DEL) | VAF 41/316 reads (13%) | called by mutect2, pindel, varscan2
- PTPRB | c.4674A>T p.K1558N | Missense Mutation (SNP) | VAF 83/324 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- PTPRD | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PTPRQ | c.3638G>T p.W1213L (on ENST00000616559; = p.W1171L on NM_001145026.2) | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PURG | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- RAB26 | c.592-5T>A | Splice Region (SNP) | VAF 34/392 reads (9%) | called by muse, mutect2
- RANBP10 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.276); called by muse, mutect2
- RASA1 | c.2198dup p.E734Gfs*33 | Frame Shift Ins (INS) | VAF 15/134 reads (11%) | called by mutect2, pindel, varscan2
- RBM25 | c.1032A>T p.E344D | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2
- REC8 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RET | c.1452G>T p.M484I | Missense Mutation (SNP) | VAF 31/390 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- RIMKLA | c.294G>T p.L98F | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- RIN2 | c.1853C>T p.S618F (on ENST00000255006 / NM_001242581.1; = p.S569F on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/1074 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); called by muse, mutect2
- RIOX1 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- RRAS | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- RRP7A | c.32G>C p.R11P | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.6524T>A p.M2175K | Missense Mutation (SNP) | VAF 20/331 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RYR2 | c.11533C>G p.L3845V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SAMD9L | c.3671C>A p.S1224Y | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- SAMD9L | c.1621G>T p.G541* | Nonsense Mutation (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- SCN7A | c.3242C>T p.A1081V | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- SCN7A | c.2060G>T p.G687V | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINB4 | c.196A>T p.T66S | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SETBP1 | c.3533C>A p.A1178D | Missense Mutation (SNP) | VAF 115/553 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SETD5 | c.1527C>T p.T509= | Splice Region (SNP) | VAF 18/136 reads (13%) | called by muse, varscan2
- SETX | c.4567A>T p.I1523F | Missense Mutation (SNP) | VAF 98/485 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- SFSWAP | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SGIP1 | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- SH2D4B | c.1288C>A p.L430M (on ENST00000646907; = p.S355Y on NM_207372.2) | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2
- SH2D5 | c.1202G>T p.G401V (on ENST00000444387 / NM_001103161.2; = p.G317V on NM_001103160.2) | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SH3BP5L | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 59/459 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHISA9 | c.744G>T p.M248I | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.954); called by muse, mutect2
- SHLD2 | c.1181G>C p.R394T | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2
- SHOX | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 45/512 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2
- SLC17A6 | c.1401G>T p.M467I | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC18A1 | c.260dup p.N87Kfs*7 | Frame Shift Ins (INS) | VAF 33/302 reads (11%) | called by mutect2, pindel, varscan2
- SLC4A1 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 82/356 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SLC4A7 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.115); called by mutect2, varscan2
- SMAP2 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOCS4 | c.1076G>C p.G359A | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SPATA31D1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 24/708 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- SPATA31D3 | c.2595C>A p.H865Q | Missense Mutation (SNP) | VAF 71/569 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPATS1 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.223); called by muse, mutect2
- SSTR2 | c.212A>T p.Y71F | Missense Mutation (SNP) | VAF 132/534 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- SSU72P8 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- STARD9 | c.12802G>T p.A4268S | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); called by muse, mutect2
- STEAP1B | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STK32B | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- STOX1 | c.106_116del p.V36Ffs*66 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel
- SYT4 | c.632del p.L211Rfs*33 | Frame Shift Del (DEL) | VAF 48/282 reads (17%) | called by mutect2, pindel*, varscan2
- TAB3 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); called by muse, mutect2
- TACR3 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TAF5L | c.1277dup p.A427Gfs*11 | Frame Shift Ins (INS) | VAF 89/576 reads (15%) | called by mutect2, pindel, varscan2
- TAZ | c.460+5G>T | Splice Region (SNP) | VAF 31/349 reads (9%) | called by muse, mutect2
- TBC1D8 | c.885G>T p.R295S | Missense Mutation (SNP) | VAF 40/382 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- TBC1D8 | c.884G>T p.R295M | Missense Mutation (SNP) | VAF 41/377 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TDRD15 | c.55C>A p.H19N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- TEX47 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7A | c.2906G>T p.W969L | Missense Mutation (SNP) | VAF 17/476 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- TIAM2 | c.3010C>A p.Q1004K | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- TIMD4 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 55/540 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TMEM14B | c.46T>G p.F16V | Missense Mutation (SNP) | VAF 57/445 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- TMPRSS11B | c.84G>T p.L28F | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNKS2 | c.2751C>G p.I917M | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- TRIM51GP | c.10G>T p.G4* | Nonsense Mutation (SNP) | VAF 20/292 reads (7%) | called by muse, mutect2
- TRIM6-TRIM34 | c.2363G>A p.G788E | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM77 | c.1298T>A p.L433H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2
- TRPC5 | c.1691C>A p.A564D | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TSEN2 | c.1015T>G p.F339V | Missense Mutation (SNP) | VAF 16/421 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TTC28 | c.1290G>T p.K430N | Missense Mutation (SNP) | VAF 50/396 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- UNC13C | c.3639T>A p.D1213E | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- UNC13C | c.3640G>T p.G1214W | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP17L2 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 40/632 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2
- USP26 | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- USP9X | c.5611C>A p.H1871N | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- VAV3 | c.2342G>T p.G781V | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13D | c.3351G>T p.E1117D | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- VWA3A | c.1280T>C p.L427P | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR44 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 17/384 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.106); called by muse, mutect2
- WIZ | c.3029G>T p.G1010V (on ENST00000673675 / NM_001371589.1; = p.G187V on NM_001330395.4) | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- XKR3 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XRN2 | c.367A>T p.K123* | Nonsense Mutation (SNP) | VAF 49/309 reads (16%) | called by muse, mutect2, varscan2
- ZBTB24 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 50/356 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZC3H10 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 18/568 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZC3HAV1 | c.2470G>A p.A824T | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZFP57 | c.968A>G p.H323R | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF268 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 52/299 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF335 | c.1099G>T p.D367Y | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ZNF33A | c.517G>T p.G173W (on ENST00000458705 / NM_006974.3; = p.G174W on NM_006954.2) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF518A | c.2122G>T p.G708* | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- ZNF518A | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, mutect2
- ZNF541 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 105/498 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZNF763 | c.935G>T p.C312F (on ENST00000358987 / NM_001367172.2; = p.C315F on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.493G>C p.A165P | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF804B | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF865 | c.2416G>T p.G806C | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF99 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA13 | c.10758C>T p.S3586= | Silent (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- ACSM2B | c.36C>A p.T12= | Silent (SNP) | VAF 18/178 reads (10%) | catalogued as rs1480284248; called by muse, mutect2, varscan2
- ACTRT2 | c.766C>T p.L256= | Silent (SNP) | VAF 21/236 reads (9%) | catalogued as rs1291330237, COSV101007596; called by muse, mutect2
- ADAM12 | c.2235C>A p.T745= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- ADAMTS8 | c.2205G>A p.L735= | Silent (SNP) | VAF 18/422 reads (4%) | catalogued as rs879170614; called by muse, mutect2
- ADGRA1 | c.105G>T p.G35= | Silent (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- ADGRB3 | c.1410C>T p.S470= | Silent (SNP) | VAF 33/238 reads (14%) | called by muse, mutect2, varscan2
- ADGRG4 | c.2220C>A p.S740= | Silent (SNP) | VAF 13/211 reads (6%) | called by muse, mutect2
- AIM2 | c.603C>T p.F201= | Silent (SNP) | VAF 8/242 reads (3%) | catalogued as COSV63699486; called by muse, mutect2
- ALPL | c.675C>T p.Y225= | Silent (SNP) | VAF 12/216 reads (6%) | catalogued as rs920960980; called by muse, mutect2
- APOA5 | c.810C>A p.A270= | Silent (SNP) | VAF 88/472 reads (19%) | catalogued as COSV57062520; called by muse, mutect2, varscan2
- ARL11 | c.381T>A p.P127= | Silent (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- ARMC5 | c.864C>T p.S288= | Silent (SNP) | VAF 17/220 reads (8%) | catalogued as rs1462281624; called by muse, mutect2
- ASB18 | c.1054C>T p.L352= | Silent (SNP) | VAF 33/609 reads (5%) | called by muse, mutect2
- BRD1 | c.1125C>T p.T375= | Silent (SNP) | VAF 30/403 reads (7%) | called by muse, mutect2
- BRD3 | c.1596G>A p.Q532= | Silent (SNP) | VAF 21/357 reads (6%) | called by muse, mutect2
- BTN2A1 | c.1245G>A p.L415= | Silent (SNP) | VAF 21/408 reads (5%) | catalogued as rs1264082559; called by muse, mutect2
- C8orf89 | c.327G>A p.E109= | Silent (SNP) | VAF 17/236 reads (7%) | catalogued as rs1291516696; called by muse, mutect2
- CCDC15 | c.1482G>T p.L494= | Silent (SNP) | VAF 56/358 reads (16%) | called by muse, varscan2
- CCR10 | c.453G>C p.R151= | Silent (SNP) | VAF 129/479 reads (27%) | called by muse, mutect2, varscan2
- CD109 | c.2808G>A p.L936= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- CDC42BPG | c.2127G>T p.L709= | Silent (SNP) | VAF 33/295 reads (11%) | catalogued as COSV100712130; called by muse, mutect2, varscan2
- CDH10 | c.2022C>G p.T674= | Silent (SNP) | VAF 157/685 reads (23%) | catalogued as COSV52586615; called by muse, mutect2, varscan2
- CDH7 | c.132G>A p.R44= | Silent (SNP) | VAF 14/207 reads (7%) | catalogued as COSV59893248; called by muse, mutect2
- CES1 | c.453C>T p.T151= | Silent (SNP) | VAF 56/1318 reads (4%) | catalogued as rs1397356144, COSV100828665; called by muse, mutect2
- CNKSR2 | c.1884C>A p.A628= | Silent (SNP) | VAF 9/216 reads (4%) | called by muse, mutect2
- CNNM1 | c.1332A>G p.S444= | Silent (SNP) | VAF 50/355 reads (14%) | called by muse, mutect2, varscan2
- CNTN5 | c.2061C>A p.A687= | Silent (SNP) | VAF 22/206 reads (11%) | called by muse, mutect2, varscan2
- COL11A1 | c.42C>T p.L14= | Silent (SNP) | VAF 18/479 reads (4%) | called by muse, mutect2
- CPT1C | c.114C>G p.S38= | Silent (SNP) | VAF 75/319 reads (24%) | called by muse, mutect2, varscan2
- CRACDL | c.754C>T p.L252= | Silent (SNP) | VAF 110/705 reads (16%) | called by muse, mutect2, varscan2
- CRISP3 | c.177T>C p.F59= (on ENST00000371159 / NM_001368123.1; = p.F41= on NM_006061.4) | Silent (SNP) | VAF 25/361 reads (7%) | called by muse, mutect2
- CRISPLD2 | c.1323G>A p.K441= | Silent (SNP) | VAF 14/312 reads (4%) | called by muse, mutect2
- CSMD2 | c.960C>A p.P320= | Silent (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- CTNND2 | c.199C>A p.R67= | Silent (SNP) | VAF 77/329 reads (23%) | catalogued as COSV58867697; called by muse, mutect2, varscan2
- CX3CR1 | c.183G>A p.K61= | Silent (SNP) | VAF 28/190 reads (15%) | catalogued as COSV64194972; called by muse, mutect2, varscan2
- CYP7B1 | c.1353C>G p.G451= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- DMRTB1 | c.357C>T p.F119= | Silent (SNP) | VAF 42/307 reads (14%) | called by muse, mutect2, varscan2
- DNAH11 | c.4353G>T p.A1451= | Silent (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2
- DPP6 | c.969C>A p.V323= (on ENST00000377770 / NM_001364500.2; = p.V261= on NM_001936.5) | Silent (SNP) | VAF 28/162 reads (17%) | called by muse, mutect2, varscan2
- DSP | c.2763C>T p.N921= | Silent (SNP) | VAF 32/254 reads (13%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.1701T>C p.N567= | Silent (SNP) | VAF 9/185 reads (5%) | called by muse, mutect2
- EGR2 | c.777C>G p.P259= | Silent (SNP) | VAF 36/240 reads (15%) | catalogued as rs750955966; called by muse, mutect2, varscan2
- EMILIN2 | c.1539T>A p.G513= | Silent (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2, varscan2
- EMX2 | c.294C>T p.P98= | Silent (SNP) | VAF 32/281 reads (11%) | called by muse, mutect2, varscan2
- EPB41L3 | c.1263G>T p.A421= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV100550068; called by muse, mutect2, varscan2
- EPHA6 | c.3012C>A p.L1004= | Silent (SNP) | VAF 17/167 reads (10%) | catalogued as rs1465391690; called by muse, mutect2, varscan2
- ERVFRD-1 | c.756C>A p.P252= | Silent (SNP) | VAF 54/204 reads (26%) | called by muse, mutect2, varscan2
- EVC | c.2622G>T p.L874= | Silent (SNP) | VAF 21/562 reads (4%) | catalogued as rs1399378301; called by muse, mutect2
- EVC2 | c.609G>T p.L203= | Silent (SNP) | VAF 31/341 reads (9%) | catalogued as COSV60390703; called by muse, mutect2
- FAM43A | c.666G>C p.P222= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as rs748069915; called by muse, mutect2, varscan2
- FARP1 | c.1200T>C p.G400= | Silent (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- FBLL1 | c.324C>G p.V108= | Silent (SNP) | VAF 12/209 reads (6%) | called by muse, mutect2
- FLNC | c.7590C>A p.T2530= | Silent (SNP) | VAF 52/548 reads (9%) | called by muse, mutect2
- GABRA6 | c.1290A>G p.A430= | Silent (SNP) | VAF 13/267 reads (5%) | catalogued as COSV99195121; called by muse, mutect2
- GJD2 | c.345C>A p.A115= | Silent (SNP) | VAF 36/394 reads (9%) | called by muse, mutect2
- GPC3 | c.921G>A p.V307= | Silent (SNP) | VAF 20/458 reads (4%) | catalogued as COSV100892972; called by muse, mutect2
- GRIN3B | c.1647C>T p.F549= | Silent (SNP) | VAF 17/392 reads (4%) | called by muse, mutect2
- GRIP2 | c.2082G>A p.T694= (on ENST00000619221; = p.T597= on NM_001080423.4) | Silent (SNP) | VAF 16/225 reads (7%) | catalogued as rs537880841, COSV99817240; called by muse, mutect2
- GUCY2F | c.846T>C p.D282= | Silent (SNP) | VAF 23/254 reads (9%) | catalogued as COSV54306801; called by muse, mutect2
- H4C3 | c.311G>A p.*104= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs771490255, COSV58091110; called by muse, varscan2
- HCN4 | c.417C>A p.P139= | Silent (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- HK3 | c.399G>T p.L133= | Silent (SNP) | VAF 31/227 reads (14%) | called by muse, varscan2
- HRNR | c.2742T>C p.G914= | Silent (SNP) | VAF 173/903 reads (19%) | called by muse, mutect2, varscan2
- HSPG2 | c.7596G>T p.V2532= | Silent (SNP) | VAF 16/306 reads (5%) | called by muse, mutect2
- IGKV2D-29 | c.214C>T p.L72= | Silent (SNP) | VAF 98/564 reads (17%) | called by muse, mutect2, varscan2
- IL21R | c.1125C>A p.S375= | Silent (SNP) | VAF 40/346 reads (12%) | called by muse, mutect2, varscan2
- ILF2 | c.229C>T p.L77= | Silent (SNP) | VAF 10/133 reads (8%) | called by muse, mutect2
- IRF2 | c.228A>T p.T76= | Silent (SNP) | VAF 31/274 reads (11%) | called by muse, mutect2, varscan2
- ISM1 | c.477G>T p.R159= | Silent (SNP) | VAF 116/611 reads (19%) | called by muse, mutect2, varscan2
- ITIH2 | c.888C>A p.V296= | Silent (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- KCNA7 | c.681C>A p.R227= | Silent (SNP) | VAF 80/345 reads (23%) | catalogued as COSV55504582; called by muse, mutect2, varscan2
- KCNMA1 | c.1701C>A p.G567= | Silent (SNP) | VAF 43/461 reads (9%) | called by muse, mutect2
- KIAA0930 | c.1149G>T p.T383= (on ENST00000336156 / NM_001009880.2; = p.T388= on NM_015264.2) | Silent (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- KIAA1549L | c.4161C>T p.L1387= (on ENST00000321505; = p.L1684= on NM_012194.3) | Silent (SNP) | VAF 12/120 reads (10%) | called by muse, varscan2
- KIAA1614 | c.1194C>A p.T398= | Silent (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- LHX4 | c.480C>A p.P160= | Silent (SNP) | VAF 102/545 reads (19%) | called by muse, mutect2, varscan2
- LMTK2 | c.2388C>T p.V796= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV51998348; called by muse, mutect2
- MAGEE1 | c.1110C>G p.P370= | Silent (SNP) | VAF 31/402 reads (8%) | called by muse, mutect2
- MANEA | c.747G>A p.P249= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs376285454; called by muse, varscan2
- MAPK4 | c.1575C>A p.R525= | Silent (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2
- MECP2 | c.1308T>C p.T436= | Silent (SNP) | VAF 54/823 reads (7%) | called by muse, mutect2
- MEIS1 | c.942C>G p.L314= | Silent (SNP) | VAF 13/332 reads (4%) | catalogued as COSV99714214; called by muse, mutect2
- MKRN3 | c.765G>T p.G255= | Silent (SNP) | VAF 16/322 reads (5%) | called by muse, mutect2
- MN1 | c.2928A>T p.P976= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs1467690488; called by muse, mutect2
- MRAP | c.183C>A p.S61= | Silent (SNP) | VAF 30/665 reads (5%) | called by muse, mutect2
- MRPL16 | c.9G>A p.R3= | Silent (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2
- MYH1 | c.1278A>T p.A426= | Silent (SNP) | VAF 41/368 reads (11%) | called by muse, mutect2, varscan2
- NAAA | c.660C>T p.I220= | Silent (SNP) | VAF 26/276 reads (9%) | called by muse, mutect2
- NAV2 | c.1128A>G p.A376= (on ENST00000396087 / NM_001244963.2; = p.A353= on NM_145117.5) | Silent (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- NCOR2 | c.4611G>T p.R1537= | Silent (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- NLGN4X | c.375C>A p.P125= | Silent (SNP) | VAF 31/451 reads (7%) | called by muse, mutect2
- NRN1 | c.243G>A p.T81= | Silent (SNP) | VAF 55/352 reads (16%) | catalogued as rs145961184; called by muse, mutect2, varscan2
- OIT3 | c.693T>C p.N231= | Silent (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- OPRD1 | c.27C>A p.A9= | Silent (SNP) | VAF 23/184 reads (13%) | called by muse, mutect2, varscan2
- OR11H6 | c.882G>T p.L294= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as COSV100209934; called by muse, mutect2
- OR2L2 | c.522T>C p.N174= | Silent (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2
- OR5H1 | c.882T>C p.N294= | Silent (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- OR5H15 | c.342C>G p.L114= | Silent (SNP) | VAF 41/300 reads (14%) | catalogued as COSV100736734; called by muse, mutect2, varscan2
- OSBPL1A | c.474A>T p.T158= | Silent (SNP) | VAF 26/204 reads (13%) | called by muse, mutect2, varscan2
- PCDH17 | c.2979T>C p.T993= | Silent (SNP) | VAF 19/274 reads (7%) | catalogued as rs1221439225; called by muse, mutect2
- PCDHA8 | c.1465C>T p.L489= | Silent (SNP) | VAF 122/907 reads (13%) | catalogued as COSV65330587; called by muse, mutect2, varscan2
- PCDHB1 | c.759G>A p.E253= | Silent (SNP) | VAF 25/274 reads (9%) | catalogued as rs137926825; called by muse, mutect2
- PCDHB7 | c.1083C>A p.P361= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs1554280086, COSV50753698, COSV50754712, COSV50767393; called by muse, mutect2, varscan2
- PGBD1 | c.621G>T p.V207= | Silent (SNP) | VAF 64/422 reads (15%) | called by muse, mutect2, varscan2
- PIK3C2A | c.2391C>T p.D797= | Silent (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2
- PKD1L2 | c.2943C>A p.A981= | Silent (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- PLXNB3 | c.138C>T p.R46= | Silent (SNP) | VAF 20/328 reads (6%) | called by muse, mutect2
- PLXNB3 | c.1402C>A p.R468= | Silent (SNP) | VAF 31/270 reads (11%) | catalogued as COSV62795465, COSV62803678; called by mutect2, varscan2
- POU3F2 | c.1245C>A p.P415= | Silent (SNP) | VAF 35/232 reads (15%) | called by muse, mutect2, varscan2
- PPP1R32 | c.633C>A p.S211= | Silent (SNP) | VAF 23/178 reads (13%) | called by muse, mutect2, varscan2
- PTK7 | c.2799G>T p.A933= | Silent (SNP) | VAF 37/474 reads (8%) | catalogued as COSV57851448; called by muse, mutect2
- PURG | c.438C>T p.S146= | Silent (SNP) | VAF 27/275 reads (10%) | catalogued as rs138893308; called by muse, mutect2, varscan2
- RBM20 | c.1056C>A p.P352= | Silent (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2
- RHOBTB1 | c.1665C>T p.D555= | Silent (SNP) | VAF 23/314 reads (7%) | called by muse, mutect2
- RNASE11 | c.393C>A p.V131= | Silent (SNP) | VAF 24/248 reads (10%) | called by muse, mutect2
- RNF128 | c.309G>C p.T103= | Silent (SNP) | VAF 40/363 reads (11%) | catalogued as COSV55252887, COSV99718274; called by muse, mutect2, varscan2
- ROR2 | c.885C>A p.P295= | Silent (SNP) | VAF 56/327 reads (17%) | called by muse, mutect2, varscan2
- RTL1 | c.888G>A p.Q296= | Silent (SNP) | VAF 34/270 reads (13%) | called by muse, mutect2, varscan2
- RXFP3 | c.237G>T p.R79= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- SBNO1 | c.2607C>T p.L869= (on ENST00000420886; = p.L868= on NM_018183.5) | Silent (SNP) | VAF 7/140 reads (5%) | catalogued as rs1218108946, COSV57343261; called by muse, mutect2
- SEMA5B | c.991C>T p.L331= | Silent (SNP) | VAF 97/623 reads (16%) | called by muse, mutect2, varscan2
- SERPINA7 | c.798G>T p.L266= | Silent (SNP) | VAF 31/380 reads (8%) | catalogued as COSV59666663; called by muse, mutect2
- SETBP1 | c.3534C>A p.A1178= | Silent (SNP) | VAF 114/544 reads (21%) | catalogued as COSV56330334; called by mutect2, varscan2
- SETD1A | c.2010G>T p.G670= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- SLC17A8 | c.492C>T p.I164= | Silent (SNP) | VAF 30/410 reads (7%) | called by muse, mutect2
- SLC28A3 | c.1110C>A p.T370= | Silent (SNP) | VAF 36/232 reads (16%) | catalogued as rs756665459, COSV66154439; called by muse, mutect2, varscan2
- SLC4A2 | c.657G>T p.S219= | Silent (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2
- SLC7A3 | c.180T>C p.D60= | Silent (SNP) | VAF 50/373 reads (13%) | called by muse, mutect2, varscan2
- SLC9A9 | c.1284C>A p.P428= | Silent (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- SPTA1 | c.3051G>T p.V1017= | Silent (SNP) | VAF 18/539 reads (3%) | called by muse, mutect2
- SYN2 | c.654C>A p.S218= | Silent (SNP) | VAF 28/219 reads (13%) | called by muse, mutect2, varscan2
- TBC1D22A | c.291G>T p.T97= | Silent (SNP) | VAF 40/279 reads (14%) | catalogued as rs147056286; called by muse, mutect2, varscan2
- TENM2 | c.3159C>A p.T1053= (on ENST00000518659 / NM_001122679.2; = p.T821= on NM_001080428.3) | Silent (SNP) | VAF 13/62 reads (21%) | called by mutect2, varscan2
- TENT5D | c.294G>A p.Q98= | Silent (SNP) | VAF 42/371 reads (11%) | called by muse, mutect2, varscan2
- TEX13A | c.717G>A p.E239= | Silent (SNP) | VAF 20/423 reads (5%) | catalogued as COSV61144104; called by muse, mutect2
- TLR4 | c.1063A>C p.R355= (on ENST00000355622 / NM_138554.5; = p.R315= on NM_003266.4) | Silent (SNP) | VAF 26/180 reads (14%) | called by muse, mutect2, varscan2
- TMC2 | c.915T>A p.S305= | Silent (SNP) | VAF 49/219 reads (22%) | called by muse, mutect2, varscan2
- TMEM131L | c.4719G>C p.P1573= | Silent (SNP) | VAF 34/450 reads (8%) | catalogued as COSV53645432; called by muse, mutect2
- TMEM225 | c.498C>A p.T166= | Silent (SNP) | VAF 30/197 reads (15%) | called by muse, mutect2, varscan2
- TRIP12 | c.63C>T p.A21= | Silent (SNP) | VAF 24/306 reads (8%) | catalogued as rs373813337, COSV99390693; called by muse, mutect2
- TRPC5 | c.648C>A p.P216= | Silent (SNP) | VAF 25/252 reads (10%) | called by muse, mutect2, varscan2
- TRPM2 | c.582G>T p.L194= | Silent (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- TTC24 | c.940C>A p.R314= | Silent (SNP) | VAF 23/327 reads (7%) | catalogued as COSV100964382; called by muse, mutect2
- UNC5B | c.1578C>T p.S526= | Silent (SNP) | VAF 25/444 reads (6%) | catalogued as rs775350591, COSV58979039; called by muse, mutect2
- UNC80 | c.7644A>C p.A2548= | Silent (SNP) | VAF 55/264 reads (21%) | called by muse, mutect2, varscan2
- USH2A | c.7428C>T p.G2476= | Silent (SNP) | VAF 73/484 reads (15%) | catalogued as rs150372183; called by muse, mutect2, varscan2
- VN1R2 | c.573C>T p.I191= | Silent (SNP) | VAF 8/212 reads (4%) | called by muse, mutect2
- VNN1 | c.693C>A p.T231= | Silent (SNP) | VAF 32/228 reads (14%) | catalogued as COSV63390805; called by muse, mutect2, varscan2
- VWA5B1 | c.99C>T p.A33= | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as rs1389306565; called by muse, mutect2
- WAS | c.177T>G p.P59= | Silent (SNP) | VAF 75/493 reads (15%) | catalogued as CD941815; called by muse, mutect2, varscan2
- WNK2 | c.2298C>A p.A766= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as COSV99945252; called by muse, mutect2, varscan2
- WWP1 | c.231A>G p.T77= | Silent (SNP) | VAF 17/162 reads (10%) | catalogued as rs748952586; called by muse, mutect2, varscan2
- ZFHX4 | c.2271T>A p.S757= | Silent (SNP) | VAF 31/272 reads (11%) | catalogued as rs768311097; called by muse, mutect2, varscan2
- ZFHX4 | c.7368C>A p.P2456= | Silent (SNP) | VAF 16/468 reads (3%) | called by muse, mutect2
- ZNF350 | c.315A>G p.E105= | Silent (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- ZP4 | c.1440T>C p.S480= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as rs764133810; called by muse, mutect2, varscan2
- AKT2 | c.-85+9887T>C | Intron (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- AL359195.2 | n.3564T>A | RNA (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- AL450442.1 | n.827C>A | RNA (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- ARPC5 | c.*4055G>T | 3'UTR (SNP) | VAF 43/327 reads (13%) | called by muse, mutect2, varscan2
- BBS4 | c.*373G>C | 3'UTR (SNP) | VAF 24/361 reads (7%) | called by muse, mutect2
- BSG | c.416-82A>T | Intron (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- CCDC191 | chr3:114056537 C>T | 5'Flank (SNP) | VAF 31/396 reads (8%) | called by muse, mutect2
- CRIP2 | chr14:105474814 G>T | 5'Flank (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- CRISP2 | c.515+161A>T | Intron (SNP) | VAF 29/201 reads (14%) | called by muse, mutect2, varscan2
- DCHS2 | n.8219C>G | RNA (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- DCHS2 | n.3446G>A | RNA (SNP) | VAF 17/428 reads (4%) | called by muse, mutect2
- DCHS2 | n.2444C>A | RNA (SNP) | VAF 24/222 reads (11%) | called by muse, mutect2, varscan2
- DHX40P1 | n.1104C>A | RNA (SNP) | VAF 32/434 reads (7%) | called by muse, mutect2
- DHX40P1 | n.1103C>A | RNA (SNP) | VAF 29/432 reads (7%) | called by muse, mutect2
- DMTF1 | c.711-176A>G | Intron (SNP) | VAF 24/196 reads (12%) | catalogued as COSV100487537; called by muse, varscan2
- ERVV-1 | chr19:53009990 G>T | 5'Flank (SNP) | VAF 53/207 reads (26%) | called by muse, mutect2, varscan2
- FAM110C | c.*25G>T | 3'UTR (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- FANCA | c.1225+47G>T | Intron (SNP) | VAF 22/259 reads (8%) | called by muse, mutect2
- FOLH1B | n.961G>T | RNA (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- FOXP2 | c.*2545G>T | 3'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- HBE1 | c.-267+102053C>T | Intron (SNP) | VAF 19/137 reads (14%) | catalogued as rs747308599; called by mutect2, varscan2
- IGFN1 | c.1242-450G>T | Intron (SNP) | VAF 44/271 reads (16%) | catalogued as COSV55168251; called by muse, mutect2, varscan2
- KCNQ2 | c.*48del | 3'UTR (DEL) | VAF 29/105 reads (28%) | called by mutect2, pindel, varscan2
- KLC1 | c.1650+7625G>C | Intron (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- KRT8P11 | n.753G>T | RNA (SNP) | VAF 17/342 reads (5%) | catalogued as rs1265348137; called by muse, mutect2
- LINC01546 | n.465C>A | RNA (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- LINC02249 | n.395G>T | RNA (SNP) | VAF 12/106 reads (11%) | called by mutect2, varscan2
- LINC02249 | n.396G>T | RNA (SNP) | VAF 10/108 reads (9%) | called by mutect2, varscan2
- LRFN4 | c.*163C>G | 3'UTR (SNP) | VAF 11/210 reads (5%) | called by muse, mutect2
- MRNIP | c.126+1957G>T | Intron (SNP) | VAF 34/293 reads (12%) | called by muse, mutect2, varscan2
- MSL3 | c.102+336G>C | Intron (SNP) | VAF 20/246 reads (8%) | catalogued as rs777434724; called by muse, mutect2
- MTG1 | c.573+59C>A | Intron (SNP) | VAF 32/425 reads (8%) | called by muse, mutect2
- MUC19 | n.5999C>A | RNA (SNP) | VAF 46/441 reads (10%) | catalogued as rs886322957; called by muse, mutect2, varscan2
- MYCL | c.-363G>T | 5'UTR (SNP) | VAF 38/197 reads (19%) | called by muse, mutect2, varscan2
- NSG2 | c.*231_*232del | 3'UTR (DEL) | VAF 38/290 reads (13%) | called by mutect2, varscan2*
- OBP2B | c.277+243C>T | Intron (SNP) | VAF 59/326 reads (18%) | called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53396A>G | Intron (SNP) | VAF 57/425 reads (13%) | catalogued as rs1176739032; called by muse, mutect2, varscan2
- PYGL | c.1519-28G>T | Intron (SNP) | VAF 32/277 reads (12%) | catalogued as COSV53585206; called by muse, mutect2, varscan2
- RAB8B | c.125-21712C>T | Intron (SNP) | VAF 14/228 reads (6%) | called by muse, mutect2
- RBMX | chrX:136872328 A>C | 3'Flank (SNP) | VAF 15/245 reads (6%) | called by muse, mutect2
- RGS2 | c.-5C>A | 5'UTR (SNP) | VAF 64/458 reads (14%) | catalogued as rs751951851; called by muse, mutect2, varscan2
- RICTOR | c.-4C>G | 5'UTR (SNP) | VAF 22/542 reads (4%) | called by muse, mutect2
- RNA5S17 | chr1:228650250 G>C | 5'Flank (SNP) | VAF 48/517 reads (9%) | called by muse, mutect2
- SNORD116-3 | n.63C>A | RNA (SNP) | VAF 20/436 reads (5%) | called by muse, mutect2
- SUGCT | c.1089+2732G>T | Intron (SNP) | VAF 39/333 reads (12%) | called by muse, mutect2, varscan2
- TAFA5 | c.112+56826G>T | Intron (SNP) | VAF 39/258 reads (15%) | catalogued as COSV60996550; called by muse, mutect2, varscan2
- TCF4 | c.287-8999G>T | Intron (SNP) | VAF 18/152 reads (12%) | catalogued as rs916780156; called by muse, mutect2, varscan2
- TEKT4P2 | n.414C>A | RNA (SNP) | VAF 12/257 reads (5%) | called by muse, mutect2
- TIE1 | c.1043-40C>A | Intron (SNP) | VAF 51/372 reads (14%) | called by muse, mutect2, varscan2
- TNNT3 | c.116-50G>A | Intron (SNP) | VAF 32/440 reads (7%) | catalogued as rs777783710, COSV53488726; called by muse, mutect2
- TPM1 | c.772+90G>T | Intron (SNP) | VAF 32/264 reads (12%) | called by muse, mutect2, varscan2
- TRIM9 | c.1604-3889A>T | Intron (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- TTC6 | chr14:37795298 A>G | 5'Flank (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.34264+4813T>A | Intron (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- UBL4A | c.155-34G>A | Intron (SNP) | VAF 22/201 reads (11%) | catalogued as rs1557212803; called by muse, mutect2
- VIM | c.1008+13C>T | Intron (SNP) | VAF 34/519 reads (7%) | called by muse, mutect2
- WDR33 | c.626+350C>G | Intron (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- XIRP2 | c.-55G>A | 5'UTR (SNP) | VAF 21/153 reads (14%) | called by muse, mutect2, varscan2
- ZIC4 | c.*10C>A | 3'UTR (SNP) | VAF 8/207 reads (4%) | catalogued as rs983350737, COSV67170927; called by muse, mutect2
